Somatic mutation profile of tumor specimen TCGA-77-A5GF-01A (aliquot TCGA-77-A5GF-01A-21D-A27K-08) from TCGA case TCGA-77-A5GF, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.2 years (25,654 days).
Specimen TCGA-77-A5GF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69b23cb9-1639-4f3e-858f-958c034897e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5GF-10A (Blood Derived Normal), aliquot TCGA-77-A5GF-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a20481c-6890-4159-a788-cc5161381592

The open-access MAF lists 117 somatic variants for this specimen: 91 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 22, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 3, RNA 3, Splice Region 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.4271G>C p.C1424S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520740, CM1413050, COSV99985786; ClinVar: pathogenic; called by muse, mutect2
- NFE2L2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960047; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 69/90 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGAP1 | c.2113A>G p.R705G (on ENST00000304032 / NM_001037131.3; = p.R652G on NM_014914.5) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100367109; called by muse, mutect2, varscan2
- AHNAK2 | c.5347G>C p.E1783Q | Missense Mutation (SNP) | VAF 199/296 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV100318952; called by muse, mutect2, varscan2
- ALK | c.2132G>A p.S711N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV101202699; called by muse, mutect2, varscan2
- ARID1A | c.3715G>T p.A1239S | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.272); catalogued as COSV100253458, COSV61375369; called by muse, mutect2, varscan2
- BAZ2B | c.2262G>C p.Q754H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100601011, COSV100601105; called by muse, mutect2, varscan2
- BRCA2 | c.6703A>T p.M2235L | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101204651; called by muse, mutect2, varscan2
- C7orf33 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV100188929; called by muse, mutect2, varscan2
- CACNA1A | c.4560A>T p.Q1520H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100803222; called by muse, mutect2, varscan2
- CDKN2A | c.34_35insG p.S12Cfs*3 | Frame Shift Ins (INS) | VAF 44/80 reads (55%) | catalogued as COSV100447958; called by mutect2, pindel, varscan2
- CDRT1 | c.622T>A p.S208T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV99887908; called by muse, mutect2, varscan2
- CEP162 | c.1920C>G p.F640L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.81); PolyPhen benign (0.12); catalogued as COSV100003406; called by muse, mutect2, varscan2
- CEP63 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100133111, COSV59674801; called by muse, mutect2, varscan2
- CLCA4 | c.2293G>T p.V765F | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV100991201; called by muse, mutect2, varscan2
- COL5A3 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99318219; called by muse, mutect2, varscan2
- COL7A1 | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.18); PolyPhen benign (0.327); catalogued as COSV100097729; called by muse, mutect2, varscan2
- CTNNA3 | c.1226A>T p.K409M | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101051613, COSV65577192; called by muse, mutect2, varscan2
- DERA | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as rs1362794638, COSV101397517; called by muse, mutect2, varscan2
- DIS3L2 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.744); catalogued as COSV99806940, COSV99807263; called by muse, mutect2, varscan2
- DRD1 | c.765A>T p.Q255H | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0.021); catalogued as COSV101192525, COSV67104481; called by muse, mutect2, varscan2
- DTX1 | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99986571; called by muse, varscan2
- FAM118A | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.908); catalogued as COSV53417776; called by muse, mutect2, varscan2
- FAM47A | c.2280G>T p.R760S | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100650086; called by muse, mutect2, varscan2
- FHL5 | c.116A>T p.N39I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100459797; called by muse, mutect2, varscan2
- FHL5 | c.160-1G>C p.X54_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100459800, COSV100459851, COSV58738588; called by muse, mutect2, varscan2
- FHL5 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100459801; called by muse, mutect2, varscan2
- FMN1 | c.3415G>A p.E1139K (on ENST00000616417 / NM_001277313.2; = p.E916K on NM_001103184.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57929738; called by muse, mutect2, varscan2
- FNDC1 | c.1957G>T p.A653S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as COSV51947258, COSV99796870; called by muse, mutect2, varscan2
- GPR65 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99966162; called by muse, mutect2, varscan2
- GRIA2 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV99645971; called by muse, mutect2, varscan2
- GTF2IRD1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as rs782564236, COSV56086077; called by muse, mutect2
- HECW2 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1440602780, COSV99649051; called by muse, mutect2, varscan2
- HNRNPH2 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99516606; called by muse, mutect2, varscan2
- HUS1B | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 53/113 reads (47%) | catalogued as COSV100034239, COSV57872373; called by muse, mutect2, varscan2
- IGKV1-27 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs180686877; called by muse, mutect2, varscan2
- IL12A | c.355T>A p.C119S | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99975875; called by muse, mutect2, varscan2
- JOSD1 | c.262A>G p.M88V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99320212; called by muse, mutect2, varscan2
- LACC1 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV100354798; called by muse, mutect2, varscan2
- LAMB1 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs371601447, COSV99741681; called by muse, mutect2, varscan2
- LAMC3 | c.3824T>C p.L1275P | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV100736092; called by muse, mutect2, varscan2
- LRP6 | c.90C>G p.D30E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99744508; called by muse, mutect2, varscan2
- MBL2 | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100906415; called by muse, mutect2, varscan2
- ME3 | c.560A>T p.D187V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100042520; called by muse, mutect2
- MEIOC | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100740296; called by muse, mutect2, varscan2
- MOGS | c.1561C>T p.H521Y | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs774128079, COSV99270791; called by muse, mutect2, varscan2
- MUC16 | c.30887G>C p.R10296P | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.676); catalogued as COSV67474078; called by muse, mutect2, varscan2
- NLRP3 | c.2879C>T p.S960F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.308); catalogued as COSV100276658; called by muse, mutect2, varscan2
- NME6 | c.398C>G p.S133C (on ENST00000415053; = p.S141C on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100189461; called by muse, mutect2, varscan2
- NPTX2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs770430126, COSV55718875; called by muse, mutect2, varscan2
- OR11A1 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV101010742; called by muse, mutect2, varscan2
- OR13C8 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100623026, COSV58611693; called by muse, mutect2, varscan2
- OR2G3 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100180773, COSV60680868; called by muse, mutect2, varscan2
- OR2T8 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100178478, COSV60662050; called by muse, mutect2, varscan2
- OR4C12 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV100078685; called by muse, mutect2, varscan2
- OR8J3 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.213); catalogued as COSV100041021; called by muse, mutect2, varscan2
- OR8U1 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1474818466, COSV100164132; called by muse, mutect2, varscan2
- P3H4 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100821302, COSV62679764; called by muse, mutect2, varscan2
- PAN3 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1405542441, COSV56701645; called by muse, mutect2, varscan2
- PCDHB13 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV53393614; called by muse, mutect2
- PPP1R3A | c.3206C>A p.S1069* | Nonsense Mutation (SNP) | VAF 12/99 reads (12%) | catalogued as COSV99494292; called by muse, mutect2, varscan2
- PPP1R3A | c.2666C>G p.S889* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV52890918, COSV99494298; called by muse, mutect2, varscan2
- PYHIN1 | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100932418; called by muse, mutect2, varscan2
- RCOR3 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100879695; called by muse, mutect2, varscan2
- ROBO1 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.969); catalogued as COSV101518048; called by muse, mutect2, varscan2
- SGSM1 | c.3010G>T p.E1004* (on ENST00000400359 / NM_001039948.4; = p.E943* on NM_133454.3) | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV101241076, COSV101241161; called by muse, mutect2, varscan2
- SLAMF9 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1208007929, COSV100928197; called by muse, mutect2, varscan2
- SLC20A1 | c.1813G>T p.A605S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as COSV99734241; called by muse, mutect2, varscan2
- SLC6A20 | c.1627C>A p.Q543K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.257); catalogued as COSV100653987; called by muse, mutect2, varscan2
- SLCO1A2 | c.1812G>T p.L604F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV56599506; called by muse, mutect2, varscan2
- SMARCA5 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV99304215; called by muse, mutect2
- SPAG9 | c.3465T>A p.C1155* (on ENST00000262013 / NM_001130528.3; = p.C1141* on NM_003971.6) | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100006003; called by muse, mutect2, varscan2
- SPICE1 | c.1219C>G p.H407D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55622397, COSV55623402, COSV99871814; called by muse, mutect2, varscan2
- STOML1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV100382045; called by muse, mutect2, varscan2
- TLR8 | c.2467G>T p.V823F (on ENST00000218032 / NM_138636.5; = p.V841F on NM_016610.4) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.643); catalogued as COSV99487295; called by muse, mutect2, varscan2
- TMEM200A | c.536G>T p.R179M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.235); catalogued as COSV99760096; called by muse, mutect2, varscan2
- TMEM200A | c.537G>T p.R179S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99760098; called by muse, mutect2, varscan2
- TMEM8B | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs969693098, COSV65076800; called by muse, mutect2, varscan2
- TRPS1 | c.1490A>G p.K497R (on ENST00000220888 / NM_001330599.2; = p.K510R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.075); catalogued as COSV99634440; called by muse, mutect2, varscan2
- TTN | c.77383C>A p.P25795T (on ENST00000591111; = p.P18371T on NM_003319.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | PolyPhen benign (0.018); catalogued as COSV100630219; called by muse, mutect2, varscan2
- USP9X | c.7601A>T p.Y2534F | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100200105; called by muse, mutect2, varscan2
- WDR54 | c.873G>A p.E291= | Splice Region (SNP) | VAF 27/139 reads (19%) | catalogued as COSV99269967; called by muse, mutect2, varscan2
- ZNF875 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100183556; called by muse, mutect2, varscan2
- ZP3 | c.313-1G>T p.X105_splice (on ENST00000394857 / NM_001110354.2; = p.X54_splice on NM_007155.6) | Splice Site (SNP) | VAF 44/73 reads (60%) | catalogued as COSV100334715; called by muse, mutect2, varscan2
- AFF4 | c.2589del p.K863Nfs*63 | Frame Shift Del (DEL) | VAF 34/77 reads (44%) | called by mutect2, pindel, varscan2
- CXCL9 | c.191+1_191+2del p.X64_splice | Splice Site (DEL) | VAF 72/155 reads (46%) | called by mutect2, pindel, varscan2
- LILRA6 | c.606C>G p.N202K | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- RESF1 | c.5169del p.E1724Kfs*23 | Frame Shift Del (DEL) | VAF 42/208 reads (20%) | called by pindel, varscan2
- RYR1 | c.7744_7745del p.M2582Afs*19 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- TBC1D3B | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AGAP3 | c.2208G>A p.K736= (on ENST00000622464; = p.K772= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs763160751, COSV101257434; called by muse, mutect2, varscan2
- ATMIN | c.2172G>A p.L724= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as COSV100214771; called by muse, mutect2, varscan2
- CCDC102A | c.1377G>T p.R459= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99265231; called by muse, mutect2, varscan2
- CHST4 | c.1160A>G p.*387= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100632952; called by muse, mutect2, varscan2
- CLEC9A | c.705T>C p.Y235= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV100191745; called by muse, mutect2, varscan2
- COL15A1 | c.4080G>A p.K1360= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as rs145656693; called by muse, mutect2
- CTTNBP2 | c.249G>A p.P83= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs759604104, COSV99354872; called by muse, mutect2, varscan2
- FAM50B | c.546C>T p.D182= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs780894143, COSV100976612; called by muse, mutect2, varscan2
- ITPR3 | c.6426C>T p.G2142= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs752663456, COSV100968130; called by muse, mutect2, varscan2
- KLHDC8A | c.279C>T p.P93= | Silent (SNP) | VAF 59/299 reads (20%) | catalogued as rs1201511363, COSV100903877; called by muse, mutect2, varscan2
- MYO7B | c.585C>T p.I195= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101268383; called by muse, mutect2, varscan2
- P2RY14 | c.180C>G p.L60= | Silent (SNP) | VAF 72/129 reads (56%) | catalogued as rs1019944607, COSV99854706; called by muse, mutect2, varscan2
- PLA2G6 | c.372C>T p.H124= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100140722; called by muse, mutect2, varscan2
- RELL2 | c.417G>A p.K139= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV99781531; called by muse, mutect2, varscan2
- RTTN | c.2265C>A p.T755= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV99730649, COSV99733819; called by muse, mutect2, varscan2
- SLC12A4 | c.2010G>C p.L670= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99863307; called by muse, mutect2, varscan2
- SLC5A4 | c.987G>C p.V329= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV99832140; called by muse, mutect2, varscan2
- TNR | c.1425G>A p.K475= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV54891953, COSV54892419; called by muse, mutect2, varscan2
- TOX4 | c.1854G>T p.V618= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV99398612; called by muse, mutect2, varscan2
- TSNAXIP1 | c.900G>A p.L300= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs140856228; called by muse, mutect2, varscan2
- TTN | c.19149G>A p.V6383= (on ENST00000591111; = p.V5456= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV59892983; called by muse, mutect2, varscan2
- UNC5D | c.501A>T p.G167= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV99778795; called by muse, mutect2
- AC244258.1 | n.340G>C | RNA (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- ADGRE4P | n.1145G>A | RNA (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- ITGB1 | c.2331+1263C>G | Intron (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100171136; called by muse, mutect2
- RNA5-8SP2 | n.139C>G | RNA (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
